Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90S, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A90S-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

ICD O-3
Seminoma NOS 90613
Site @ Testis NOS C629
9/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

“Left testis”:

- Classic seminoma
- Neoplasia size: 0.9 x 0.7 x 0.7cm
- Sanguineous vascular invasion: not detected.
- Lymphatic vascular invasion: not detected.
- Perineural invasion: not detected.
- Intratubular neoplasia: absent.
- Rete testis: uninvolved by neoplasia.
- Tunica albuginea: uninvolved by neoplasia.
- Spermatic cord: uninvolved by neoplasia.
- Adjacent testicular parenchyma: focal atrophy.
- Margin of spermatic cord: uninvolved by neoplasia.

“End of inferior pole of left testicle”:

- uninvolved by neoplasia.

HPA Discrepancy		✓
Reviewer Initials	MA	Case Reviewed: 11/3/13

Source: NCI Genomic Data Commons file f722b2c8-5858-4961-9cf4-d587a12becde (TCGA-YU-A90S.9B16F8A5-6C34-4D93-8E43-DA111DB4F67A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).